Somatic mutation profile of tumor specimen ER-ACGR-TTM1-A (aliquot ER-ACGR-TTM1-A-1-0-D-A49L-35) from EXCEPTIONAL_RESPONDERS case ER-ACGR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.1 years (19,015 days).
Specimen ER-ACGR-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2492809a-82f8-4291-9e33-64d6b29be9f8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ACGR-NB1-A (Blood Derived Normal), aliquot ER-ACGR-NB1-A-1-0-D-A49L-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55a74970-c503-418c-8570-2579e6bd1416

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 366/678 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 116/572 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 178/443 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GATA1 | c.600G>A p.E200= | Splice Region (SNP) | VAF 205/403 reads (51%) | catalogued as rs781977639; called by muse, mutect2, varscan2
- LRP1B | c.7562G>T p.G2521V | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776244285; called by muse, mutect2, varscan2
- PTPRD | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 170/322 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV61973374; called by muse, mutect2, varscan2
- ROS1 | c.4375G>T p.A1459S | Missense Mutation (SNP) | VAF 203/431 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV63852809; called by muse, mutect2, varscan2
- SRC | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 162/454 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV62440259; called by muse, mutect2, varscan2
- WT1 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.257); catalogued as COSV100189181, COSV60072025; called by muse, mutect2, varscan2
- FANCI | c.3403A>C p.I1135L (on ENST00000310775 / NM_001376911.1; = p.I1075L on NM_018193.3) | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANCM | c.2898G>C p.E966D | Missense Mutation (SNP) | VAF 189/483 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FLT4 | c.2848G>T p.A950S | Missense Mutation (SNP) | VAF 141/221 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FUBP1 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 196/406 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GLI1 | c.2671G>T p.G891W | Missense Mutation (SNP) | VAF 77/376 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3CA | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 252/616 reads (41%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- TP53 | c.723dup p.C242Lfs*22 | Frame Shift Ins (INS) | VAF 140/405 reads (35%) | called by mutect2, pindel, varscan2
- CDKN2B | c.411G>T p.G137= | Silent (SNP) | VAF 89/362 reads (25%) | called by muse, mutect2, varscan2
- PRSS8 | c.9G>A p.Q3= | Silent (SNP) | VAF 97/158 reads (61%) | catalogued as rs562510374; called by muse, mutect2, varscan2
- TEK | c.3072T>C p.Y1024= | Silent (SNP) | VAF 108/351 reads (31%) | catalogued as COSV101193232; called by muse, mutect2, varscan2
- BCL2 | c.*2343C>A | 3'UTR (SNP) | VAF 75/237 reads (32%) | called by muse, mutect2, varscan2
